CCDI case PBBYFB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6708a1c1-9686-4ca4-b447-c788943e5901

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.9 years (701 days).

Biospecimens (3 samples)
- Sample 0DKSTS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKSVO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKSZ9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
